Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9UM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9UM-01A (Primary Tumor).

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

1-"Vaginal biopsy (anterior lower third)":
Metastatic squamous cell carcinoma in vaginal corion.

2-"Cervix biopsy":
Invasive squamous cell carcinoma, histologic grade 2.

ICD O-3

Carcinoma, squamous cell NOS
8070/3

Site: Cervix NOS
C539

QED 3/7/14

Source: NCI Genomic Data Commons file 12b7be30-c8b0-4325-aa88-4757435c4d31 (TCGA-VS-A9UM.20927111-D875-4B7E-9E8F-F8EE861600D2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).